Somatic mutation profile of tumor specimen TARGET-30-PASUCB-01A (aliquot TARGET-30-PASUCB-01A-01D) from TARGET case TARGET-30-PASUCB, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 2.8 years (1,008 days).
Specimen TARGET-30-PASUCB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff0b79c9-2e4e-49a4-b228-54f66292b582.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASUCB-10A (Blood Derived Normal), aliquot TARGET-30-PASUCB-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cc79473a-ebe6-48ba-a5da-9c804f1d0554

The open-access MAF lists 18 somatic variants for this specimen: 16 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 14, Silent 2, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH12 | c.302T>C p.V101A | Missense Mutation (SNP) | VAF 69/165 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV66418941; called by muse, mutect2, varscan2
- CLPTM1 | c.1340G>T p.R447M | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as COSV61612320; called by muse, mutect2, varscan2
- CNTN6 | c.1121C>T p.T374M | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.892); catalogued as rs745410696, COSV63178028; called by muse, mutect2, varscan2
- DIPK1C | c.896A>C p.D299A | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59725549; called by muse, varscan2
- HEATR6 | c.2788C>T p.R930W | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758324010, COSV51746818; called by muse, mutect2, varscan2
- HPS3 | c.2640G>T p.L880F | Missense Mutation (SNP) | VAF 67/174 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV56055540; called by muse, mutect2, varscan2
- KL | c.2642C>G p.A881G | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0.266); catalogued as COSV66309182; called by muse, mutect2, varscan2
- MARVELD2 | c.1021C>A p.Q341K | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV57781298; called by muse, mutect2, varscan2
- NUP210 | c.3798G>T p.Q1266H | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.061); catalogued as COSV54408721; called by muse, mutect2, varscan2
- OR52D1 | c.356T>C p.L119P | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as COSV59487841; called by muse, mutect2, varscan2
- SIN3B | c.2805G>C p.R935S | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.8); PolyPhen benign (0.005); catalogued as COSV56134332; called by muse, mutect2, varscan2
- SLC41A1 | c.393G>T p.K131N | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV65650275, COSV65650878; called by muse, mutect2, varscan2
- ZNF292 | c.6337C>A p.P2113T | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV60541916; called by muse, mutect2, varscan2
- NCAPG | c.1682_1683dup p.I562Lfs*8 | Frame Shift Ins (INS) | VAF 20/54 reads (37%) | called by mutect2, pindel, varscan2
- NLRP10 | c.1800_1816del p.N600Kfs*8 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | called by mutect2, pindel
- NOMO1 | c.3593G>T p.G1198V | Missense Mutation (SNP) | VAF 32/411 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.154); called by muse, mutect2
- OR5R1 | c.375C>A p.A125= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as COSV56572355; called by muse, mutect2
- OTOL1 | c.240C>T p.G80= | Silent (SNP) | VAF 80/171 reads (47%) | catalogued as COSV60007308; called by muse, mutect2, varscan2
